CCDI case PBBLSC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/897c9201-e7cd-4eb9-8234-9483213d9c8e

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.9 years (4,356 days).

Biospecimens (3 samples)
- Sample 0DBXXV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBXXW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DBXXY: Tissue type: Tumor; Specimen type: Solid Tissue.
